Gene-level copy-number profile of tumor specimen TCGA-44-5644-01A from TCGA case TCGA-44-5644, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 51.0 years (18,644 days).
Specimen TCGA-44-5644-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.ddfbf239-f672-42a1-ab09-59fa43c63f08.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-44-5644-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44ea7fc9-f92d-4beb-8100-69ab787cc31c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 2,057; copy number 2: 22,766; copy number 3: 20,819; copy number 4: 8,585; copy number 5: 2,392; copy number 6: 1,064; copy number 7: 870; copy number 8: 310; copy number 9: 294; copy number 10: 259; copy number 11: 209; copy number 12: 142; copy number 13: 6; copy number 16: 15; copy number 18: 1; copy number 19: 1; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-44-5644-01A-21D-2035-01): tumor purity 0.75, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:22,518,414–22,667,671, 13 genes: AC011467.6, AC011467.1, LINC01233, RNU6-1179P, AC011467.5, GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4, RAD54L2P1, LINC01785, AC011467.2, ZNF492.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,540 genes in 61 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,247,272–16,667,524, 74 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr1:39,154,164–43,623,666, 150 genes, copy number 5–18 (broad region; genes not listed).
- chr1:149,937,812–154,870,281, 270 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr2:134,455,759–135,047,468, 9 genes, copy number 12 (within-gene range 3–12): TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19.
- chr2:148,863,564–150,047,447, 16 genes, copy number 5: UBBP3, KIF5C-AS1, RPS20P13, USP8P2, KIF5C, AC105402.1, LYPD6B, TXNP5, AC009230.1, FAM8A3P, LYPD6, RPL17P13, MMADHC, MMADHC-DT, RNU6-601P, LINC01931.
- chr2:151,832,771–152,284,460, 6 genes, copy number 5 (within-gene range 4–5): CACNB4, AC079790.1, STAM2, RPL30P2, AC079790.2, Y_RNA.
- chr3:64,010,550–79,767,998, 177 genes, copy number 5–8 (broad region; genes not listed).
- chr3:96,566,357–96,814,407, 7 genes, copy number 5: AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1.
- chr3:105,366,909–118,810,836, 187 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr4:46,918,900–47,838,106, 12 genes, copy number 5–7: GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1.
- chr5:58,198–27,121,150, 425 genes, copy number 6–16 (broad region; genes not listed).
- chr5:28,213,359–42,721,878, 225 genes, copy number 6–11 (within-gene range 4–11) (broad region; genes not listed).
- chr5:55,307,989–63,302,056, 117 genes, copy number 5–9 (broad region; genes not listed).
- chr5:90,353,037–91,612,566, 22 genes, copy number 5: AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2.
- chr6:30,541,377–31,140,092, 44 genes, copy number 5 (within-gene range 3–5): GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN.
- chr7:21,215,537–41,133,507, 395 genes, copy number 5 (broad region; genes not listed).
- chr7:107,628,553–110,592,204, 33 genes, copy number 5–8: WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1, AC002386.1, AC073071.1, AC073387.1, AC073387.2, EIF3IP1, RPL3P8, AC073114.1, AC073114.2, AC073326.2.
- chr7:113,876,777–115,833,373, 18 genes, copy number 5–7: PPP1R3A, FOXP2, AC073626.2, AC073626.1, AC003992.1, RNA5SP238, MIR3666, MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA.
- chr7:124,032,126–125,482,966, 18 genes, copy number 5 (within-gene range 3–5): AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93.
- chr7:150,716,606–150,861,504, 8 genes, copy number 5 (within-gene range 3–5): GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1.
- chr8:35,862,123–36,321,404, 9 genes, copy number 6 (within-gene range 2–6): AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 6–13 (broad region; genes not listed).
- chr9:26,895,678–29,318,952, 29 genes, copy number 5–12: RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1.
- chr10:76,835,377–79,677,996, 50 genes, copy number 12: AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1, AC012560.1, LINC00595, AC010163.3, AC010163.1, AC010163.2, SNORA71, AL583852.1, AC016820.1, ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2.
- chr11:35,431,823–35,918,739, 9 genes, copy number 6 (within-gene range 4–6): PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, AC090692.2, KRT18P14, AC090692.3, AC090692.1.
- chr12:66,767–1,495,933, 27 genes, copy number 6 (within-gene range 4–6): IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1.
- chr12:25,779,287–26,421,462, 18 genes, copy number 6: RN7SKP262, AC019209.3, TDGP1, AC019209.2, MIR4302, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1.
- chr12:37,575,587–40,570,832, 38 genes, copy number 7: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:94,515,476–133,214,832, 958 genes, copy number 5–7 (broad region; genes not listed).
- chr13:55,535,697–68,037,131, 95 genes, copy number 5 (broad region; genes not listed).
- chr14:43,300,263–44,386,064, 8 genes, copy number 9 (within-gene range 2–15): HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P, LINC02307, EIF4BP1, AL109766.1.
- chr15:93,230,034–94,726,519, 22 genes, copy number 5 (within-gene range 3–5): AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580, LINC01581, AC104390.1, H3P40, MCTP2, AC135626.1, AC135626.2, AC009432.2, LINC02852, AC009432.1, AC022308.1.
- chr16:18,926,863–19,706,793, 27 genes, copy number 5 (within-gene range 4–5): AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, LINC02858, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L.
- chr17:52,390,515–55,842,830, 32 genes, copy number 5–19 (within-gene range 3–19): LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP.
- chr17:71,596,338–73,663,848, 34 genes, copy number 5: AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4, SDK2, AC124804.1, AC032019.1, AC032019.2.
- chr18:1,509,022–2,655,395, 15 genes, copy number 5–6 (within-gene range 3–6): AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3, AP005136.4, METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2.
- chr18:7,301,020–8,406,861, 9 genes, copy number 5 (within-gene range 4–5): AP005270.1, AP001095.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1.
- chr18:30,713,275–42,691,422, 149 genes, copy number 5 (broad region; genes not listed).
- chr18:62,187,255–64,019,779, 36 genes, copy number 5: RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8.
- chr22:18,906,028–21,977,632, 182 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,754. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
